Somatic mutation profile of tumor specimen 0DJO5F from CCDI case PBBXFJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.2 years (1,907 days).
Specimen 0DJO5F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c517b29c-88f7-48fd-8ca5-070bd03a8661.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJO4R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30638816-10f2-49bf-a1b4-cc4df2fe1a35

The open-access MAF lists 4 somatic variants for this specimen: 1 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Intron 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PDYN | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.156); catalogued as COSV99453200; called by muse, mutect2
- KCNK9 | c.867C>T p.D289= | Silent (SNP) | VAF 29/449 reads (6%) | catalogued as rs1327148194, COSV57289341; called by muse, mutect2
- SLC4A11 | c.2262G>A p.T754= | Silent (SNP) | VAF 92/410 reads (22%) | catalogued as rs376249499; called by muse, mutect2, varscan2
- FLII | c.3206+29_3206+32del | Intron (DEL) | VAF 121/362 reads (33%) | called by mutect2, varscan2
